Somatic mutation profile of tumor specimen TCGA-VS-A8EH-01A (aliquot TCGA-VS-A8EH-01A-11D-A36J-09) from TCGA case TCGA-VS-A8EH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,728 days).
Specimen TCGA-VS-A8EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be15f9c4-66fb-4dcf-ab6b-3ff3ce96d65c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EH-10A (Blood Derived Normal), aliquot TCGA-VS-A8EH-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16978210-1fd4-4fbe-9669-663662ca6994

The open-access MAF lists 67 somatic variants for this specimen: 43 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 23, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 80/162 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- AFAP1L2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs367978439; called by muse, mutect2, varscan2
- ALG13 | c.1858C>G p.H620D | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.15); catalogued as COSV99323283; called by muse, mutect2, varscan2
- ALS2 | c.2003G>T p.G668V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99970191; called by muse, mutect2, varscan2
- ASXL3 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1161873364, COSV99327040; called by muse, mutect2, varscan2
- C6 | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs775903405, COSV99667971; called by muse, mutect2, varscan2
- CAMTA1 | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1285071931, COSV100352770; called by muse, mutect2, varscan2
- CDHR3 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs372834692; called by muse, mutect2, varscan2
- CHIT1 | c.77G>T p.C26F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99705655; called by muse, mutect2, varscan2
- DEPDC1 | c.1955G>A p.R652Q (on ENST00000456315 / NM_001114120.3; = p.R368Q on NM_017779.6) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs745857232, COSV100920527; called by muse, mutect2, varscan2
- ENPP2 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99309593; called by muse, mutect2, varscan2
- FLRT3 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs537766361, COSV54074740; called by muse, mutect2, varscan2
- GSTCD | c.1210G>A p.V404I (on ENST00000360505 / NM_001031720.3; = p.V317I on NM_024751.3) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100853886; called by muse, mutect2, varscan2
- HIPK1 | c.3166C>T p.P1056S (on ENST00000369558 / NM_001369806.1; = p.P662S on NM_181358.2) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100479781; called by muse, mutect2, varscan2
- KIF26B | c.3031G>A p.A1011T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs760038696, COSV100833638; called by muse, mutect2, varscan2
- LAMA1 | c.8977G>T p.V2993F | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101057882; called by muse, mutect2, varscan2
- LIMCH1 | c.3005C>T p.S1002L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1193655554, COSV100574694; called by muse, mutect2, varscan2
- LZTS1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763241069; called by muse, mutect2, varscan2
- MAN2B1 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV55472319; called by muse, mutect2, varscan2
- MFSD14A | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV99791171; called by muse, mutect2, varscan2
- MMP15 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs751230902, COSV99539802; called by muse, mutect2, varscan2
- NEDD1 | c.1210A>G p.S404G | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1462255785, COSV99901449; called by muse, mutect2, varscan2
- OR4D9 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373176580; called by muse, mutect2, varscan2
- OR5V1 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.389); catalogued as rs777739188, COSV101011526; called by muse, mutect2, varscan2
- PCDHB14 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.185); catalogued as rs145800994; called by muse, mutect2, varscan2
- PCDHGA6 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs200515281; called by muse, mutect2, varscan2
- PLAC1 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100821684; called by muse, mutect2, varscan2
- PRADC1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.988); catalogued as rs372220247, COSV57820066; called by muse, mutect2, varscan2
- RANBP2 | c.2467A>G p.K823E | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.45); catalogued as rs770490577, COSV99313572; called by muse, mutect2, varscan2
- RNF17 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99694709; called by muse, mutect2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- RYR2 | c.13805G>C p.R4602P | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100773293, COSV63712107; called by muse, mutect2, varscan2
- SORCS3 | c.3490G>A p.E1164K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63817037; called by muse, mutect2, varscan2
- TBC1D19 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs747990019, COSV53514450, COSV53518195, COSV99336908; called by muse, mutect2, varscan2
- TBC1D8B | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99345180; called by muse, mutect2, varscan2
- TMCC1 | c.1321G>A p.A441T (on ENST00000393238 / NM_001349268.2; = p.A117T on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs148011506; called by muse, mutect2, varscan2
- TOR1B | c.170G>C p.C57S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99400359; called by muse, mutect2, varscan2
- ZBTB49 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs769459955, COSV100552645; called by muse, mutect2, varscan2
- ZNF484 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); catalogued as COSV100214944; called by muse, mutect2, varscan2
- ZNF600 | c.990C>G p.Y330* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100593135; called by muse, mutect2, varscan2
- ZNF761 | c.295T>C p.F99L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.278); catalogued as COSV100483523; called by muse, mutect2, varscan2
- ZSWIM4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.228); catalogued as COSV99585538; called by muse, mutect2, varscan2
- CHD7 | c.501G>A p.P167= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs770348243, COSV71109787; called by muse, mutect2, varscan2
- CLNK | c.978G>A p.E326= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV57018517; called by muse, mutect2, varscan2
- CLTCL1 | c.1131T>C p.Y377= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99596054; called by muse, mutect2, varscan2
- COLEC12 | c.1902C>T p.F634= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV101232216, COSV68373568; called by muse, mutect2, varscan2
- ECE2 | c.249C>G p.L83= | Silent (SNP) | VAF 88/100 reads (88%) | catalogued as COSV100668926; called by muse, mutect2, varscan2
- FANCI | c.3669G>A p.L1223= (on ENST00000310775 / NM_001376911.1; = p.L1163= on NM_018193.3) | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as COSV51525561; called by muse, mutect2, varscan2
- FARP2 | c.2805T>C p.Y935= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs769980116, COSV99885765; called by muse, mutect2, varscan2
- FNDC1 | c.639T>C p.D213= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99797300; called by muse, mutect2, varscan2
- GJA8 | c.855G>T p.G285= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV99569816; called by muse, mutect2, varscan2
- IL17RA | c.2427G>A p.T809= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100083524; called by muse, mutect2, varscan2
- MYO1D | c.2175G>C p.L725= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100555082; called by muse, mutect2, varscan2
- NIPAL2 | c.609A>G p.K203= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as COSV100358804; called by muse, mutect2
- NOL8 | c.718A>C p.R240= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100694729; called by muse, mutect2, varscan2
- OR5H1 | c.309G>A p.S103= | Silent (SNP) | VAF 50/62 reads (81%) | catalogued as rs779446848, COSV63401624, COSV63401900; called by muse, mutect2, varscan2
- PABPC5 | c.1011G>A p.V337= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV100442756, COSV57042510; called by muse, mutect2, varscan2
- PCLO | c.13629G>A p.A4543= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs771864365, COSV100426565, COSV100439248; called by muse, mutect2, varscan2
- SLC4A1AP | c.642G>A p.Q214= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100389722; called by muse, mutect2, varscan2
- SLIT3 | c.1380C>T p.S460= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as rs771710067, COSV100265173; called by muse, mutect2, varscan2
- TFDP3 | c.252C>G p.A84= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV100033608; called by muse, mutect2, varscan2
- TNFRSF10B | c.732G>A p.L244= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52393044; called by muse, mutect2, varscan2
- TRIM25 | c.477G>A p.Q159= | Silent (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- TTC13 | c.1647G>A p.S549= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs1157441384, COSV64167834; called by muse, mutect2, varscan2
- ZNF318 | c.2967G>A p.Q989= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100546587; called by muse, mutect2, varscan2
- PTPRK | c.100+28526dup | Intron (INS) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
